TCGA case TCGA-CC-A8HV — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b32d3f4-9b88-42de-aaac-22d1d2f5cde0

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 51 years; Vital status: Dead; Days to death: 279 days.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 51.8 years (18,935 days); Year of diagnosis: 2013; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 279 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib Tosylate; Days to treatment start: 158 days; Days to treatment end: 188 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS). Age at diagnosis: 52.2 years (19,084 days); Days to diagnosis: 149 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 52.5 years (19,176 days); Days to diagnosis: 241 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for initial diagnosis; Organ Transplantation to Liver, for initial diagnosis; Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Day 149 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 149 days.
- Days to follow up: 279 days; Disease response: With Tumor.
- ECOG performance status: 2.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 51 kg; Height: 159 cm; BMI: 20.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CC-A8HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-CC-A8HV-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CC-A8HV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CC-A8HV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment: Pharmaceutical therapy drug name: Nexavar; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 279 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 279 days; disease-free interval: event (new tumor event after initially disease-free), 149 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 149 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CC-A8HV-01A-11D-A40C-01): tumor purity 0.82, ploidy 3.39, whole-genome doublings 1.
